Somatic mutation profile of tumor specimen 0DFKHR from CCDI case PBBSJN, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Temporal lobe; Age at diagnosis: 5.3 years (1,947 days).
Specimen 0DFKHR: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 279b0e8f-4e41-4010-bb91-ced850b8b415.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DFKHT (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/26564432-2a0c-4c4b-aa0e-2e6e8c3e30e0

The open-access MAF lists 9 somatic variants for this specimen: 5 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 4, Silent 4, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.865G>A p.A289T | Missense Mutation (SNP) | VAF 572/1149 reads (50%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs769696078, COSV51770322, COSV99297135; ClinVar: likely pathogenic; called by muse, varscan2
- DNTT | c.307G>T p.D103Y | Missense Mutation (SNP) | VAF 184/616 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs755771727, COSV64522725; called by muse, varscan2
- DOCK3 | c.346C>T p.R116C | Missense Mutation (SNP) | VAF 150/588 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as rs761053993; called by muse, varscan2
- PLA2G4C | c.847C>T p.R283* | Nonsense Mutation (SNP) | VAF 173/420 reads (41%) | catalogued as rs754481101; called by muse, varscan2
- SULT2A1 | c.5C>T p.S2L | Missense Mutation (SNP) | VAF 263/816 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.14); catalogued as rs989081337, COSV55766230; called by muse, varscan2
- CDYL2 | c.1359C>T p.A453= | Silent (SNP) | VAF 366/923 reads (40%) | catalogued as rs146529911; called by muse, varscan2
- EHBP1L1 | c.3351G>A p.A1117= | Silent (SNP) | VAF 166/604 reads (27%) | catalogued as rs1295005925, COSV58574125; called by muse, varscan2
- PIWIL1 | c.1704C>T p.Y568= | Silent (SNP) | VAF 210/845 reads (25%) | catalogued as rs151261790; called by muse, varscan2
- SLC38A5 | c.705C>T p.L235= | Silent (SNP) | VAF 134/1240 reads (11%) | catalogued as rs142925547, COSV58333754, COSV58333853; called by muse, varscan2
